Somatic mutation profile of tumor specimen TCGA-05-4405-01A (aliquot TCGA-05-4405-01A-21D-1855-08) from TCGA case TCGA-05-4405, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.6 years (27,241 days).
Specimen TCGA-05-4405-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1579ac6-e964-463a-9121-36cf21144620.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4405-10A (Blood Derived Normal), aliquot TCGA-05-4405-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/345f1cca-aabd-493a-b873-e6c3c3e5910f

The open-access MAF lists 398 somatic variants for this specimen: 297 protein-altering or splice-affecting, 93 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 256, Silent 93, Nonsense Mutation 24, Frame Shift Del 8, Splice Site 5, RNA 4, Frame Shift Ins 3, Intron 2, 5'UTR 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAD51C | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 15/138 reads (11%) | catalogued as rs1555594861, COSV53612677, COSV53625252; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2M | c.2353T>C p.S785P | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV59393097; called by muse, mutect2, varscan2
- ABCA1 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV66071323; called by muse, mutect2, varscan2
- ACTRT2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV65760681; called by muse, mutect2, varscan2
- ADGRG4 | c.4583T>A p.V1528D | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV54968271; called by muse, mutect2
- ADGRG4 | c.4996G>T p.G1666W | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54968280; called by muse, mutect2, varscan2
- ADGRG4 | c.7283T>A p.I2428N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV54968287; called by muse, mutect2, varscan2
- ADGRL3 | c.3002G>A p.R1001Q (on ENST00000506720 / NM_001322402.2; = p.R933Q on NM_015236.6) | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.888); catalogued as rs370040630; called by muse, mutect2
- ALAS1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV59630128; called by muse, mutect2, varscan2
- ALDOB | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV66398111, COSV66398756; called by muse, mutect2, varscan2
- ALG13 | c.2764C>A p.P922T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.709); catalogued as COSV52645563; called by muse, mutect2
- AMELX | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV61636692; called by muse, mutect2, varscan2
- ANK2 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV52191759; called by muse, mutect2, varscan2
- ANXA3 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53717741; called by muse, mutect2, varscan2
- ARID3C | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs1354211294, COSV66698490; called by muse, mutect2, varscan2
- ASB14 | c.1469T>A p.L490H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV99898096; called by muse, mutect2, varscan2
- ATP2B3 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as COSV54863279; called by muse, mutect2, varscan2
- BGN | c.25T>A p.S9T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV100525315; called by muse, mutect2, varscan2
- BOD1L1 | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV50077949; called by muse, mutect2, varscan2
- C1QTNF12 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV100382655; called by muse, mutect2
- CAMTA2 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV61838627; called by muse, mutect2, varscan2
- CATSPERE | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV63682563; called by muse, mutect2
- CCNB3 | c.2626C>G p.R876G | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52080466; called by muse, mutect2, varscan2
- CDH10 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV52574669, COSV52591973; called by muse, mutect2, varscan2
- CDH6 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54079267; called by muse, mutect2, varscan2
- CDHR3 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772129631, COSV58422421; called by muse, mutect2, varscan2
- CEP83 | c.486T>G p.F162L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.479); catalogued as COSV60411599; called by muse, mutect2, varscan2
- CFAP77 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV100546177; called by muse, mutect2, varscan2
- CFAP77 | c.334T>A p.Y112N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.205); catalogued as COSV100546180; called by muse, mutect2, varscan2
- CHL1 | c.3458G>T p.R1153M (on ENST00000397491 / NM_001253387.1; = p.R1169M on NM_006614.4) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as COSV99852558; called by muse, mutect2, varscan2
- CHL1 | c.3459G>T p.R1153S (on ENST00000397491 / NM_001253387.1; = p.R1169S on NM_006614.4) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.095); catalogued as rs1401484709, COSV99852560; called by muse, mutect2, varscan2
- CHRNA7 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60972861, COSV60976906; called by muse, mutect2, varscan2
- CILP2 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1185186437, COSV52281034; called by muse, mutect2, varscan2
- CLEC1A | c.300G>T p.L100F | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59534218; called by muse, mutect2, varscan2
- CNTN2 | c.2438G>T p.R813M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.195); catalogued as COSV59353439; called by muse, mutect2, varscan2
- COL12A1 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.551); catalogued as COSV59409464; called by muse, mutect2, varscan2
- COL1A2 | c.2746G>T p.G916* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as CM070851, CM1110799, COSV51963515; called by muse, mutect2, varscan2
- COL5A2 | c.3248G>T p.G1083V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66415980; called by muse, mutect2, varscan2
- COL6A3 | c.2539A>G p.N847D | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV55112642; called by muse, mutect2, varscan2
- CPAMD8 | c.2731G>T p.V911L (on ENST00000651564; = p.V864L on NM_015692.5) | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV71597469; called by muse, mutect2, varscan2
- CPED1 | c.541-1G>T p.X181_splice | Splice Site (SNP) | VAF 35/140 reads (25%) | catalogued as COSV60000167, COSV60009431; called by muse, mutect2, varscan2
- CPNE4 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV101456833; called by muse, mutect2, varscan2
- CPNE4 | c.658G>T p.G220* | Nonsense Mutation (SNP) | VAF 69/228 reads (30%) | catalogued as COSV101456835; called by muse, mutect2, varscan2
- CPS1 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV51826132; called by muse, mutect2
- CR1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65464287; called by muse, mutect2, varscan2
- CRACR2A | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV52919143; called by muse, mutect2, varscan2
- CROT | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV58977127; called by muse, mutect2, varscan2
- CSMD2 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773143736, COSV53891996; called by muse, mutect2, varscan2
- CSMD3 | c.2827G>T p.E943* (on ENST00000297405 / NM_001363185.1; = p.E839* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV52334573; called by muse, varscan2
- CYLD | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886040880, COSV61096366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF1 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.372); catalogued as COSV60047048; called by muse, mutect2, varscan2
- DCAF12L2 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV63584420; called by muse, mutect2, varscan2
- DCBLD1 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51646691; called by muse, mutect2, varscan2
- DGKB | c.2376C>A p.C792* | Nonsense Mutation (SNP) | VAF 73/246 reads (30%) | catalogued as COSV51782465, COSV99341128; called by muse, mutect2, varscan2
- DIS3L2 | c.1300G>T p.V434F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56064917; called by muse, mutect2, varscan2
- DLGAP2 | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70104175; called by muse, mutect2
- DMD | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs141028860, COSV55894314; called by muse, mutect2, varscan2
- DOCK11 | c.352A>T p.K118* | Nonsense Mutation (SNP) | VAF 31/175 reads (18%) | catalogued as COSV52248524; called by muse, mutect2, varscan2
- DOCK11 | c.2758T>A p.F920I | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV52248532; called by muse, mutect2
- DPYD | c.1574A>G p.Y525C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64616575; called by muse, mutect2, varscan2
- DRG2 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV56729617; called by muse, mutect2
- DSTYK | c.1381A>T p.I461F | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV65688674; called by muse, mutect2
- DYNC1H1 | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV64143511, COSV64143712; called by muse, mutect2
- EFHB | c.1658A>G p.H553R | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV55554301; called by muse, mutect2, varscan2
- EHF | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57670262; called by muse, mutect2, varscan2
- ENOX2 | c.1284C>A p.Y428* (on ENST00000338144 / NM_001382520.1; = p.Y399* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/339 reads (11%) | catalogued as COSV57658645; called by muse, mutect2, varscan2
- ENPP1 | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV62936845; called by muse, mutect2, varscan2
- EPHA5 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.96); catalogued as COSV99901702; called by muse, mutect2
- EVI5 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1381096353, COSV64830510; called by muse, mutect2, varscan2
- F13B | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 88/361 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV66375590, COSV66375901; called by muse, mutect2, varscan2
- F8 | c.4743G>T p.L1581F | Missense Mutation (SNP) | VAF 165/422 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.391); catalogued as COSV64279303; called by muse, mutect2, varscan2
- FAM171A1 | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.866); catalogued as COSV65320629; called by muse, mutect2, varscan2
- FAM47C | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63730844; called by muse, varscan2
- FAM50A | c.986C>A p.P329H | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50133438; called by muse, mutect2, varscan2
- FARSA | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100108939, COSV58906178; called by muse, mutect2, varscan2
- FAT1 | c.10889A>G p.H3630R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs372958192; called by muse, mutect2, varscan2
- FAT4 | c.3776C>G p.A1259G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV67901756; called by muse, mutect2, varscan2
- FBF1 | c.2656G>T p.E886* (on ENST00000586717; = p.E900* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs907231532, COSV100045667; called by muse, mutect2, varscan2
- FBN2 | c.3136A>G p.K1046E | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV52547697; called by muse, mutect2
- FCRL2 | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 94/313 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV63835316; called by muse, mutect2, varscan2
- FDXR | c.1292C>T p.P431L (on ENST00000293195 / NM_024417.5; = p.P437L on NM_004110.6) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV99501556; called by muse, mutect2, varscan2
- FER1L6 | c.3440C>A p.P1147H | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV101205915, COSV67553064; called by muse, mutect2, varscan2
- FGG | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV60196941; called by muse, mutect2, varscan2
- FHOD3 | c.2619G>T p.Q873H (on ENST00000359247 / NM_001281739.3; = p.Q890H on NM_025135.5) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.496); catalogued as COSV57172288; called by muse, mutect2, varscan2
- FHOD3 | c.3328C>A p.L1110I (on ENST00000359247 / NM_001281739.3; = p.L1127I on NM_025135.5) | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV57190095; called by muse, mutect2, varscan2
- FIBCD1 | c.790C>A p.H264N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV53395105; called by mutect2, varscan2
- FLG2 | c.1110G>T p.W370C | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV66174018; called by muse, mutect2, varscan2
- FOXG1 | c.1080C>A p.N360K | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57397283, COSV57397953; called by muse, mutect2, varscan2
- GABBR2 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52317140; called by muse, mutect2
- GABRA4 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51935918; called by muse, mutect2, varscan2
- GATA4 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58736004; called by muse, mutect2
- GBP6 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.303); catalogued as COSV65012721; called by muse, mutect2, varscan2
- GPR174 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99338416; called by muse, mutect2
- GPR32 | c.1036T>C p.S346P | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV54515769; called by muse, mutect2, varscan2
- GPRASP1 | c.3875C>A p.T1292K | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64356590; called by muse, mutect2
- GRID2 | c.2490C>A p.S830R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs377339263; called by muse, mutect2, varscan2
- H4C11 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100748028; called by muse, mutect2, varscan2
- HAUS7 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57851403; called by muse, mutect2
- HDAC6 | c.3399T>A p.C1133* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV57807610; called by muse, mutect2, varscan2
- HECW1 | c.4349G>A p.R1450H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs777450594, COSV67823769; called by muse, mutect2, varscan2
- HOGA1 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs974889070, COSV65706784; called by muse, mutect2, varscan2
- HSPA14 | c.620T>G p.V207G | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV65685360; called by muse, mutect2, varscan2
- IDH3G | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as COSV54210399; called by muse, mutect2
- IFI16 | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV55540762; called by muse, mutect2, varscan2
- IGKV1-27 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs778478221; called by muse, mutect2
- IGSF9B | c.3640G>T p.G1214C | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as COSV58064324, COSV58073522; called by muse, mutect2, varscan2
- IRS4 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV64534415; called by muse, mutect2
- ITGAE | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53992867, COSV53998178, COSV54000588; called by muse, mutect2, varscan2
- JAM2 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); catalogued as COSV57261017; called by muse, mutect2, varscan2
- KCNH5 | c.2164C>A p.Q722K | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV59779980; called by muse, mutect2, varscan2
- KCNH8 | c.2986T>A p.S996T | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV60478503; called by muse, mutect2
- KERA | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | catalogued as COSV99899606; called by muse, mutect2
- KERA | c.434A>G p.E145G | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899608; called by muse, mutect2
- KIAA1109 | c.14050G>C p.E4684Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52695329; called by muse, mutect2, varscan2
- KIAA1109 | c.14285T>C p.V4762A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as COSV52695338; called by muse, mutect2
- KIF13A | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs752618857, COSV52467125; called by muse, mutect2
- KLHL4 | c.1697T>A p.V566D | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV64148550; called by muse, mutect2, varscan2
- KRT74 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59773856; called by muse, mutect2, varscan2
- KRTAP11-1 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV100190862; called by muse, mutect2, varscan2
- KRTAP6-1 | c.205T>A p.Y69N | Missense Mutation (SNP) | VAF 25/180 reads (14%) | PolyPhen benign (0.003); catalogued as COSV100228848; called by muse, mutect2, varscan2
- L1CAM | c.3580T>A p.S1194T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62830401; called by muse, mutect2
- LAMB2 | c.3515G>T p.R1172L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100026527, COSV59738418; called by muse, mutect2, varscan2
- LAMB4 | c.193-1G>T p.X65_splice | Splice Site (SNP) | VAF 19/92 reads (21%) | catalogued as COSV52732313; called by muse, mutect2, varscan2
- LAMB4 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV52732331; called by muse, mutect2, varscan2
- LAMC3 | c.4359G>C p.E1453D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV62655906; called by muse, mutect2, varscan2
- LILRB4 | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV54409006; called by muse, mutect2
- LMTK2 | c.706del p.D236Tfs*31 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | catalogued as COSV51994615, COSV51997411; called by pindel, varscan2
- LRFN2 | c.1346T>G p.V449G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV57835313; called by muse, mutect2, varscan2
- LRIG1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV56241326, COSV56249067; called by muse, mutect2, varscan2
- LRP1B | c.3035G>C p.R1012T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.965); catalogued as COSV67279823; called by muse, mutect2, varscan2
- LRRC37A | c.2306T>A p.L769Q | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100208301; called by mutect2, varscan2
- LRRC42 | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59962066; called by muse, mutect2, varscan2
- MAP1A | c.8032C>G p.P2678A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV55813564; called by muse, mutect2
- MAP1B | c.2371G>T p.A791S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1306226865, COSV57107278; called by muse, mutect2
- MAPK7 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55191531; called by muse, mutect2
- MBTPS2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63412630; called by muse, mutect2
- MKI67 | c.6952G>T p.G2318C | Missense Mutation (SNP) | VAF 147/596 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64077353; called by muse, mutect2, varscan2
- MUC16 | c.34387C>A p.L11463M | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV67497647; called by muse, mutect2, varscan2
- MUC16 | c.29C>A p.S10* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV101197479, COSV67497655; called by muse, mutect2
- MYH3 | c.5497A>C p.K1833Q | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV56870628; called by muse, mutect2
- NBAS | c.5199G>T p.K1733N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as COSV55739353; called by muse, mutect2
- NBAS | c.2345A>G p.N782S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1253121288, COSV55739361; called by muse, mutect2
- NBEA | c.1079T>G p.V360G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59827136; called by muse, mutect2, varscan2
- NCAPG2 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV51992279; called by muse, mutect2, varscan2
- NEXMIF | c.1908C>A p.H636Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV50152409; called by muse, mutect2, varscan2
- NKD2 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV56891719, COSV56896446; called by muse, mutect2, varscan2
- NRP2 | c.1798A>G p.T600A | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.97); catalogued as COSV55936144; called by muse, mutect2, varscan2
- NXPH2 | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 80/159 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99741385; called by muse, mutect2, varscan2
- OPHN1 | c.1073T>G p.L358R | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs745478793, COSV62787511; called by muse, mutect2, varscan2
- OPN1LW | c.665T>A p.V222D | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV100885071; called by muse, mutect2
- OPTN | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53813657; called by muse, mutect2
- OR2A12 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV68822132; called by muse, mutect2, varscan2
- OR2G3 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 145/467 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60683424; called by muse, mutect2, varscan2
- OR2T33 | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV58818277; called by muse, mutect2, varscan2
- OR5T2 | c.46C>G p.H16D | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.037); catalogued as COSV57588720, COSV57591177; called by muse, mutect2, varscan2
- OR6F1 | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.049); catalogued as COSV57469637; called by muse, mutect2, varscan2
- OTOGL | c.2041A>T p.I681F (on ENST00000547103; = p.I672F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1277272641, COSV101509525; called by muse, mutect2, varscan2
- OTOGL | c.4498T>C p.S1500P (on ENST00000547103; = p.S1491P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088005; called by muse, mutect2, varscan2
- PALLD | c.2785C>T p.H929Y (on ENST00000505667 / NM_001166108.2; = p.H912Y on NM_016081.4) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV54996259; called by muse, mutect2, varscan2
- PCDH11X | c.3560C>A p.P1187Q | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as COSV53509108; called by muse, mutect2, varscan2
- PCDHB12 | c.1290G>T p.R430S | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.974); catalogued as COSV53401552; called by muse, mutect2, varscan2
- PCDHB16 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.818); catalogued as COSV53372114; called by muse, mutect2, varscan2
- PCDHGA1 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); catalogued as COSV65294812, COSV65300168; called by muse, mutect2, varscan2
- PCDHGB1 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1438801220, COSV54043885; called by muse, mutect2, varscan2
- PDE10A | c.1202G>C p.S401T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV100604851, COSV63050501; called by muse, mutect2, varscan2
- PDE4B | c.422A>T p.D141V | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV58497822; called by muse, mutect2, varscan2
- PDZRN3 | c.3081G>T p.K1027N | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55216948; called by muse, mutect2, varscan2
- PEAK1 | c.2404G>T p.D802Y | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV56944280; called by muse, mutect2, varscan2
- PHF8 | c.2188C>A p.L730M (on ENST00000357988 / NM_001184896.1; = p.L694M on NM_015107.3) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57688597; called by muse, mutect2, varscan2
- PI4KA | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1569070823, COSV55424825; called by muse, mutect2, varscan2
- PKD1 | c.5787G>T p.E1929D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.602); catalogued as rs750663372, COSV99239213; called by muse, mutect2, varscan2
- PKD1 | c.5786A>T p.E1929V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.048); catalogued as COSV99239217; called by muse, mutect2, varscan2
- PKD1 | c.2718G>T p.E906D | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51926850; called by muse, mutect2
- PKHD1L1 | c.2414G>T p.G805V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV65754659; called by muse, mutect2, varscan2
- PPARGC1A | c.1932G>C p.R644S | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV53534118; called by muse, mutect2, varscan2
- PPOX | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.33); catalogued as COSV99237873; called by muse, mutect2, varscan2
- PPP1R32 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs770655422, COSV100087753, COSV58546299; called by muse, mutect2, varscan2
- PQBP1 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54431961; called by muse, mutect2, varscan2
- PRDM11 | c.641A>C p.K214T (on ENST00000530656 / NM_001359633.1; = p.K180T on NM_001256695.1) | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV55444193; called by muse, mutect2, varscan2
- PRDM14 | c.1216G>T p.G406W | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52575674; called by muse, mutect2, varscan2
- PRDM9 | c.279A>T p.E93D | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); catalogued as COSV57006794, COSV57014064; called by muse, mutect2, varscan2
- PRKCB | c.1768G>T p.G590C | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57804004; called by muse, mutect2, varscan2
- PSAPL1 | c.1016T>A p.L339* | Nonsense Mutation (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100040769; called by muse, mutect2, varscan2
- PZP | c.2371T>C p.S791P | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV54371408; called by muse, mutect2, varscan2
- RANBP3 | c.1346G>A p.G449E (on ENST00000340578 / NM_007322.3; = p.G444E on NM_003624.3) | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50387183; called by muse, mutect2, varscan2
- RANBP3L | c.1175C>A p.A392D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV56955378, COSV56958611; called by muse, mutect2, varscan2
- RASSF2 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV65083402; called by muse, mutect2, varscan2
- RHCG | c.1306T>C p.W436R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1270229178, COSV51518703; called by muse, mutect2, varscan2
- RHD | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as CM136877, COSV59645778, COSV59647467; called by muse, mutect2, varscan2
- RIMS2 | c.3127C>A p.L1043I (on ENST00000666250 / NM_001348490.2; = p.L851I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.04); catalogued as COSV99202504; called by muse, mutect2, varscan2
- RNF152 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.297); catalogued as rs1479729972, COSV57184429, COSV57186768; called by muse, mutect2, varscan2
- ROBO2 | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV59942485; called by muse, mutect2, varscan2
- RRN3 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52217183; called by muse, mutect2, varscan2
- RTL3 | c.1225G>T p.G409* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV58184139, COSV58186120; called by muse, mutect2, varscan2
- RTL3 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV58186128; called by muse, mutect2, varscan2
- RYR1 | c.1892T>A p.L631Q | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62112459; called by muse, mutect2, varscan2
- RYR1 | c.7537G>C p.E2513Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.32); catalogued as COSV62096625, COSV62112465; called by muse, mutect2, varscan2
- RYR2 | c.1885C>A p.Q629K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV63718000; called by muse, mutect2, varscan2
- RYR2 | c.13404C>A p.H4468Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.123); catalogued as COSV63657695, COSV63718016; called by muse, mutect2, varscan2
- SARDH | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV64097883; called by muse, mutect2, varscan2
- SCAMP3 | c.897+1G>C p.X299_splice | Splice Site (SNP) | VAF 10/92 reads (11%) | catalogued as COSV56947679; called by muse, mutect2, varscan2
- SCN9A | c.1574A>C p.H525P | Missense Mutation (SNP) | VAF 19/486 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV57626701; called by muse, mutect2
- SDK2 | c.3160C>A p.R1054S | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.326); catalogued as COSV66182577, COSV66198136; called by muse, mutect2, varscan2
- SEC31A | c.319A>T p.I107L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58882034; called by muse, mutect2, varscan2
- SEMA6D | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60384876; called by muse, mutect2, varscan2
- SEMG1 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV54874835; called by muse, mutect2, varscan2
- SEPSECS | c.1454C>G p.A485G | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV100259074; called by muse, mutect2, varscan2
- SEPTIN4 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57899961; called by muse, mutect2, varscan2
- SEPTIN4 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV58729099, COSV58729161; called by muse, mutect2, varscan2
- SETDB2 | c.222A>C p.K74N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51647203; called by muse, varscan2
- SGCA | c.535T>A p.L179M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56251287; called by muse, mutect2, varscan2
- SGTA | c.518A>G p.N173S | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV55595782; called by muse, mutect2, varscan2
- SIPA1L2 | c.3136A>G p.K1046E | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV53401172; called by muse, mutect2, varscan2
- SIRPA | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1433660920, COSV61537593; called by muse, mutect2, varscan2
- SLC10A5 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.637); catalogued as COSV101594273; called by muse, mutect2, varscan2
- SLC10A5 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV101594274; called by muse, mutect2, varscan2
- SLC45A2 | c.622G>T p.G208* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as COSV56875267, COSV56875890; called by muse, mutect2, varscan2
- SLC4A11 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.034); catalogued as COSV66264267; called by muse, mutect2, varscan2
- SLC7A9 | c.377_378insG p.I127Hfs*82 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | catalogued as COSV99195538; called by mutect2, pindel, varscan2
- SLCO1B1 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV57018104; called by muse, mutect2, varscan2
- SPAG1 | c.494A>T p.D165V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52563872; called by muse, mutect2
- SPARC | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV50561010; called by muse, mutect2
- SPATA31D1 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs776658069, COSV61201917; called by muse, mutect2, varscan2
- SPINK5 | c.1938C>A p.C646* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV56263366; called by muse, mutect2, varscan2
- ST6GAL2 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 31/87 reads (36%) | PolyPhen probably damaging (0.96); catalogued as COSV100867666, COSV64532277; called by muse, mutect2, varscan2
- STARD7 | c.505G>C p.G169R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100474558, COSV61526937; called by muse, mutect2, varscan2
- STRN4 | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV52190221; called by muse, mutect2
- SULT2B1 | c.715T>G p.S239A (on ENST00000201586 / NM_177973.2; = p.S224A on NM_004605.2) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.754); catalogued as COSV52379070; called by muse, mutect2
- SUPT6H | c.1618G>T p.G540W | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112840; called by muse, mutect2, varscan2
- SUPT6H | c.1619G>C p.G540A | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100112844, COSV58925349; called by muse, mutect2, varscan2
- SV2C | c.1915A>T p.M639L | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59230196; called by muse, mutect2
- TAB1 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53373316, COSV99335991; called by muse, mutect2, varscan2
- TAS1R2 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV64747489; called by muse, mutect2, varscan2
- TBC1D5 | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV53772799; called by muse, mutect2, varscan2
- TBC1D5 | c.1331+1G>T p.X444_splice | Splice Site (SNP) | VAF 60/266 reads (23%) | catalogued as COSV53772808; called by muse, mutect2, varscan2
- TEF | c.618C>G p.H206Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99842090; called by muse, mutect2, varscan2
- TEX15 | c.447T>A p.C149* (on ENST00000256246; = p.C532* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as COSV56354908, COSV99820733; called by muse, mutect2, varscan2
- TFAP2D | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1294724782, COSV50464821; called by muse, mutect2, varscan2
- TIAM1 | c.70A>C p.K24Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54577170; called by muse, mutect2, varscan2
- TMEM131L | c.2419G>T p.D807Y | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV53651028; called by muse, varscan2
- TMPRSS11E | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 78/546 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV59521442; called by muse, mutect2, varscan2
- TNR | c.2405A>T p.D802V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54916498; called by muse, mutect2, varscan2
- TPO | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as CM024370, COSV61098161, COSV61098304; called by muse, mutect2, varscan2
- TRIM42 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as COSV53883654; called by muse, mutect2, varscan2
- TRMT61B | c.372G>T p.M124I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60258994; called by muse, mutect2, varscan2
- TRPM6 | c.3634C>T p.Q1212* | Nonsense Mutation (SNP) | VAF 26/142 reads (18%) | catalogued as COSV62524053; called by muse, mutect2, varscan2
- TRRAP | c.10468A>T p.T3490S (on ENST00000359863 / NM_001244580.1; = p.T3461S on NM_003496.3) | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62855385; called by muse, mutect2, varscan2
- TSGA10IP | c.574T>A p.S192T | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV73245443; called by muse, mutect2
- TSPYL2 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); catalogued as COSV64921594; called by muse, mutect2
- TTC7A | c.1599G>T p.Q533H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV55416013; called by muse, mutect2, varscan2
- UBE3D | c.605A>T p.K202M | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52757946; called by muse, mutect2, varscan2
- UBFD1 | c.684A>T p.K228N | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99563502; called by muse, mutect2, varscan2
- ULK1 | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV58857779; called by muse, mutect2, varscan2
- UNC5B | c.1828A>T p.T610S | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV58981781; called by muse, mutect2, varscan2
- USP11 | c.2791G>A p.D931N (on ENST00000218348; = p.D888N on NM_001371072.1) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54476298; called by muse, mutect2, varscan2
- USP26 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as COSV100896782; called by muse, mutect2, varscan2
- USP29 | c.1118C>A p.A373D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54142304, COSV54147134; called by muse, varscan2
- USP29 | c.1170A>C p.K390N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV54147136; called by muse, varscan2
- VAV1 | c.663G>C p.L221F | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV58392256; called by muse, mutect2, varscan2
- WASHC3 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV99527665; called by muse, mutect2, varscan2
- WDR19 | c.733A>T p.I245F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV56470646; called by muse, mutect2
- WFIKKN2 | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV100260143; called by muse, mutect2, varscan2
- XIRP2 | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as rs563195903, COSV54737650; called by muse, mutect2
- YTHDF1 | c.1169G>C p.R390P | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64833993; called by muse, mutect2, varscan2
- ZDBF2 | c.2101T>G p.S701A | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV65630585; called by muse, mutect2
- ZFHX4 | c.6602C>T p.T2201M | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51474461; called by muse, mutect2
- ZFHX4 | c.10300G>T p.D3434Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV51499137; called by muse, mutect2, varscan2
- ZIM2 | c.836_837insT p.E280Gfs*7 | Frame Shift Ins (INS) | VAF 35/156 reads (22%) | catalogued as COSV99690675; called by mutect2, pindel, varscan2
- ZMAT1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV65660266; called by muse, mutect2, varscan2
- ZNF180 | c.1428G>C p.Q476H | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.461); catalogued as COSV55424850; called by muse, mutect2
- ZNF208 | c.1990C>A p.P664T | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV68113359; called by muse, varscan2
- ZNF347 | c.2227G>C p.G743R | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV61969398, COSV61971182; called by muse, mutect2, varscan2
- ZNF445 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs769475422, COSV68539733; called by muse, mutect2, varscan2
- ZNF556 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100298961; called by muse, mutect2, varscan2
- ZNF578 | c.504C>G p.H168Q | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.282); catalogued as COSV69737775; called by muse, mutect2
- ZNF596 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV57655604; called by muse, mutect2, varscan2
- ZNF76 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs368273976; called by muse, mutect2, varscan2
- ZSCAN1 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV56608889; called by muse, mutect2, varscan2
- ZYX | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.747); catalogued as COSV59557827; called by muse, varscan2
- ZZZ3 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.026); catalogued as COSV66235849; called by muse, mutect2, varscan2
- ESRRG | c.275del p.G92Efs*38 | Frame Shift Del (DEL) | VAF 56/216 reads (26%) | called by mutect2, pindel, varscan2
- GAGE2A | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 126/5866 reads (2%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- IGHV3-21 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1-6 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- IQSEC3 | c.952_953del p.A318Rfs*148 (on ENST00000538872 / NM_001170738.2; = p.A15Rfs*148 on NM_015232.1) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by pindel, varscan2
- LYST | c.6578del p.G2193Efs*38 | Frame Shift Del (DEL) | VAF 58/235 reads (25%) | called by mutect2, pindel, varscan2
- MGA | c.4109del p.G1370Afs*26 | Frame Shift Del (DEL) | VAF 36/125 reads (29%) | called by mutect2, pindel, varscan2
- NBPF26 | c.3544+1G>T p.X1182_splice (on ENST00000620612; = p.X920_splice on NM_001351372.1) | Splice Site (SNP) | VAF 19/126 reads (15%) | called by mutect2, varscan2
- PRAMEF15 | c.1058C>A p.T353N | Missense Mutation (SNP) | VAF 135/522 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SERPINE1 | c.350_351del p.T117Rfs*44 | Frame Shift Del (DEL) | VAF 81/313 reads (26%) | called by pindel, varscan2
- SIN3A | c.320del p.P107Hfs*15 | Frame Shift Del (DEL) | VAF 40/139 reads (29%) | called by mutect2, pindel, varscan2
- SLC35G6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.761); called by muse, mutect2
- SLC39A10 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); called by muse, mutect2
- SLITRK2 | c.570del p.N191Ifs*3 | Frame Shift Del (DEL) | VAF 24/223 reads (11%) | called by mutect2, pindel, varscan2
- SPSB1 | c.550dup p.D184Gfs*38 | Frame Shift Ins (INS) | VAF 20/182 reads (11%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.1086C>A p.G362= | Silent (SNP) | VAF 41/245 reads (17%) | catalogued as COSV61281770; called by muse, mutect2, varscan2
- ADCY9 | c.1716G>T p.S572= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99570994; called by muse, mutect2, varscan2
- ALPI | c.1224G>T p.T408= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs767460621, COSV55016337; called by muse, mutect2, varscan2
- ANPEP | c.831G>C p.T277= | Silent (SNP) | VAF 29/209 reads (14%) | catalogued as COSV55595625; called by muse, mutect2, varscan2
- APOA4 | c.990C>T p.G330= | Silent (SNP) | VAF 75/159 reads (47%) | catalogued as rs1287410087, COSV63361220; called by muse, mutect2, varscan2
- AQP7 | c.447C>T p.T149= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs768964172, COSV53035998; called by muse, mutect2, varscan2
- ASNS | c.1593C>T p.D531= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV51556469; called by muse, mutect2, varscan2
- AUTS2 | c.1554C>G p.P518= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs761323917, COSV61428082, COSV61432405; called by muse, mutect2, varscan2
- BGN | c.24G>T p.V8= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100525312; called by muse, mutect2, varscan2
- CACNA1E | c.2733G>C p.R911= | Silent (SNP) | VAF 11/187 reads (6%) | catalogued as COSV62431571; called by muse, mutect2
- CADM3 | c.486G>T p.R162= (on ENST00000368125 / NM_001127173.3; = p.R196= on NM_021189.5) | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV63687692; called by muse, mutect2, varscan2
- CDH4 | c.1665C>T p.H555= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs1253870362, COSV64676849; called by muse, mutect2
- CEP350 | c.5814A>G p.L1938= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV62610405; called by muse, mutect2, varscan2
- CLDN2 | c.429C>A p.I143= | Silent (SNP) | VAF 34/284 reads (12%) | catalogued as COSV61021391; called by muse, mutect2, varscan2
- CNTN1 | c.537A>G p.V179= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV61646269; called by muse, mutect2, varscan2
- COL1A2 | c.3384C>A p.L1128= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as COSV51955010, COSV51966986; called by muse, mutect2, varscan2
- CYRIB | c.48G>T p.G16= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV67833589; called by muse, mutect2, varscan2
- DDN | c.801G>A p.G267= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV100305516; called by muse, mutect2, varscan2
- DLX1 | c.603C>T p.N201= | Silent (SNP) | VAF 30/180 reads (17%) | catalogued as rs541299088, COSV59394584; called by muse, mutect2, varscan2
- DNAH5 | c.6786G>C p.G2262= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV54255626; called by muse, mutect2, varscan2
- DOCK1 | c.1362G>T p.V454= | Silent (SNP) | VAF 17/414 reads (4%) | catalogued as COSV54762395; called by muse, mutect2
- DUSP26 | c.342G>C p.L114= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99823597; called by muse, mutect2, varscan2
- ECT2L | c.804A>G p.S268= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV62887493; called by muse, mutect2
- EIF4G2 | c.1728C>T p.H576= | Silent (SNP) | VAF 72/153 reads (47%) | catalogued as COSV60599338; called by muse, mutect2, varscan2
- FAM166C | c.132C>A p.T44= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs534721835, COSV61594234; called by muse, mutect2, varscan2
- FAM47C | c.1984C>A p.R662= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV100792688, COSV63730850; called by muse, mutect2, varscan2
- FCAR | c.834C>T p.T278= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as COSV62032083; called by muse, mutect2
- FOXG1 | c.1230C>T p.L410= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as rs1318078788, COSV57395130; called by muse, mutect2
- FOXP1 | c.1812A>G p.E604= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as COSV59556073; called by muse, mutect2
- FRG2 | c.24C>A p.S8= | Silent (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- GIMAP8 | c.39C>A p.L13= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV56234505; called by muse, mutect2, varscan2
- GPR45 | c.1002C>A p.A334= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV51526362, COSV51526440; called by muse, mutect2
- HECW1 | c.4605G>A p.T1535= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs373576994, COSV67842994; called by muse, mutect2, varscan2
- HK2 | c.2670C>T p.F890= | Silent (SNP) | VAF 39/272 reads (14%) | catalogued as COSV51875650; called by muse, mutect2, varscan2
- IGKV1D-33 | c.39G>T p.L13= | Silent (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
- KLHL1 | c.294A>T p.P98= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV64785540; called by muse, mutect2, varscan2
- L1CAM | c.2019C>A p.T673= | Silent (SNP) | VAF 29/337 reads (9%) | catalogued as COSV62830415; called by muse, mutect2
- L1CAM | c.558G>T p.T186= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as rs782773215, COSV62830424; called by muse, mutect2, varscan2
- LILRB4 | c.1138C>T p.L380= (on ENST00000391733 / NM_001278428.3; = p.L379= on NM_001278426.3) | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV54409014; called by muse, mutect2, varscan2
- LRCH2 | c.471G>A p.Q157= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV57761160; called by muse, mutect2
- LRRC6 | c.343C>T p.L115= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV51548086; called by muse, mutect2, varscan2
- LTBP1 | c.3336G>A p.S1112= (on ENST00000404816 / NM_206943.4; = p.S786= on NM_000627.4) | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs139837372; called by muse, mutect2, varscan2
- MEP1A | c.876G>A p.Q292= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV57922823; called by muse, mutect2, varscan2
- NCOA1 | c.2517G>A p.A839= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs757335592, COSV56044183; called by muse, mutect2, varscan2
- NLRP5 | c.1221C>A p.V407= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV66767805; called by muse, mutect2, varscan2
- NUGGC | c.738C>T p.D246= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV58439648; called by muse, mutect2, varscan2
- OR5K1 | c.318T>A p.T106= | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as COSV60305440; called by muse, mutect2
- OR5K4 | c.108G>T p.L36= | Silent (SNP) | VAF 17/320 reads (5%) | catalogued as COSV100721420; called by muse, mutect2
- OR6N1 | c.703A>C p.R235= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV58650646; called by muse, mutect2
- PAXBP1 | c.627T>G p.S209= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs755307487, COSV51612709; called by muse, mutect2, varscan2
- PCDHB6 | c.1938C>A p.G646= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV50690192; called by muse, mutect2, varscan2
- PDE6B | c.99C>A p.A33= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV55328496, COSV55331292; called by muse, mutect2, varscan2
- PILRB | c.435C>T p.T145= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV60336672; called by muse, mutect2, varscan2
- PLD5 | c.300A>T p.S100= (on ENST00000442594; = p.S38= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as COSV59170596; called by muse, mutect2
- PLXNB1 | c.3156G>T p.V1052= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56494672; called by muse, mutect2
- POMGNT1 | c.1362G>A p.R454= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV64341114; called by muse, mutect2, varscan2
- PPOX | c.708G>A p.L236= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as COSV99237871; called by muse, mutect2, varscan2
- PRAMEF15 | c.1059C>A p.T353= | Silent (SNP) | VAF 130/516 reads (25%) | called by mutect2, varscan2
- PRKCA | c.1053A>G p.G351= | Silent (SNP) | VAF 42/200 reads (21%) | catalogued as COSV52596998; called by muse, mutect2, varscan2
- RALGAPA2 | c.2664T>G p.R888= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV52512725; called by muse, mutect2
- RIMS2 | c.3126C>A p.L1042= (on ENST00000666250 / NM_001348490.2; = p.L850= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV99202471; called by muse, mutect2, varscan2
- ROBO2 | c.180C>T p.P60= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV59942471; called by muse, mutect2
- SALL1 | c.1359C>T p.F453= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as rs749874315, COSV51765130; called by muse, mutect2, varscan2
- SDHD | c.291A>T p.A97= | Silent (SNP) | VAF 70/131 reads (53%) | catalogued as COSV54780078; called by muse, mutect2, varscan2
- SEC14L1 | c.1836G>T p.L612= | Silent (SNP) | VAF 72/278 reads (26%) | catalogued as COSV66725850; called by muse, mutect2, varscan2
- SNX25 | c.684G>T p.A228= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV53016764; called by muse, mutect2, varscan2
- SORCS1 | c.2757C>T p.G919= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as COSV53909205; called by muse, mutect2
- SPATA31D1 | c.3723C>A p.S1241= | Silent (SNP) | VAF 59/348 reads (17%) | catalogued as COSV61201926; called by muse, mutect2, varscan2
- SPEN | c.10902C>T p.F3634= | Silent (SNP) | VAF 79/230 reads (34%) | catalogued as rs746873132, COSV65268554, COSV65272201; called by muse, mutect2, varscan2
- TAS1R1 | c.366A>T p.P122= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV60230481; called by muse, mutect2
- TBX20 | c.819G>A p.T273= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs776684707, COSV68786569; called by muse, mutect2, varscan2
- TENM1 | c.63A>G p.L21= | Silent (SNP) | VAF 45/403 reads (11%) | catalogued as COSV64445052; called by muse, mutect2, varscan2
- TEX14 | c.1155C>A p.I385= (on ENST00000240361 / NM_001201457.2; = p.I379= on NM_031272.5) | Silent (SNP) | VAF 45/217 reads (21%) | catalogued as COSV53611543; called by muse, mutect2, varscan2
- TFAP2C | c.615G>T p.L205= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV52373461; called by muse, mutect2, varscan2
- TGFBR1 | c.1107A>G p.P369= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV66627140; called by muse, mutect2
- TJP1 | c.1812C>T p.F604= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV62047023; called by muse, mutect2, varscan2
- TNFAIP3 | c.1341G>T p.A447= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV52800820, COSV52802684; called by muse, mutect2, varscan2
- TRAF7 | c.1518G>C p.V506= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV58218726; called by muse, mutect2, varscan2
- TTN | c.64224C>T p.I21408= (on ENST00000591111; = p.I13984= on NM_003319.4) | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV60382408; called by muse, mutect2, varscan2
- TUBA3D | c.177C>A p.G59= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV58313520; called by muse, mutect2, varscan2
- TUFM | c.273G>A p.K91= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs570472566, COSV100493238; called by muse, mutect2, varscan2
- UBE2J1 | c.768G>T p.R256= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV70562636; called by muse, mutect2, varscan2
- UBQLN4 | c.426G>T p.G142= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV64145892; called by muse, mutect2, varscan2
- UGT1A8 | c.549C>T p.C183= | Silent (SNP) | VAF 44/442 reads (10%) | catalogued as COSV65087159; called by muse, mutect2
- UTP14A | c.921G>A p.K307= | Silent (SNP) | VAF 15/202 reads (7%) | catalogued as COSV64087962; called by muse, mutect2
- WFIKKN2 | c.426C>A p.P142= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100260138; called by muse, mutect2, varscan2
- XIRP2 | c.9000C>A p.P3000= (on ENST00000628543; = p.P3175= on NM_152381.6) | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV54737668; called by muse, mutect2, varscan2
- ZNF17 | c.726A>T p.G242= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV56922663; called by muse, mutect2, varscan2
- ZNF513 | c.1413C>T p.P471= | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as COSV52011091; called by muse, mutect2, varscan2
- ZNF665 | c.1203C>G p.V401= (on ENST00000600412; = p.V466= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/115 reads (4%) | catalogued as COSV67217868; called by muse, mutect2
- ZSWIM3 | c.903C>T p.A301= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV54852021; called by muse, mutect2, varscan2
- ZUP1 | c.117G>C p.V39= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV100885010, COSV63944879; called by muse, mutect2, varscan2
- ZYX | c.1005G>C p.P335= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV59557835; called by muse, varscan2
- AL136982.4 | n.1735G>T | RNA (SNP) | VAF 35/233 reads (15%) | called by muse, mutect2, varscan2
- FRMPD2B | n.838G>T | RNA (SNP) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- KIF1B | c.2115+6337G>A | Intron (SNP) | VAF 5/97 reads (5%) | catalogued as COSV99824306; called by muse, mutect2
- MIR1270 | chr19:20397829 A>T | 3'Flank (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- OR1N2 | c.-18T>A | 5'UTR (SNP) | VAF 34/129 reads (26%) | catalogued as COSV65461310; called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1270C>T | RNA (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- UGT1A6 | c.862-23246C>A | Intron (SNP) | VAF 30/348 reads (9%) | catalogued as COSV59400038; called by muse, mutect2
- ZNF271P | n.1466G>C | RNA (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
